Somatic mutation profile of tumor specimen TCGA-CV-6433-01A (aliquot TCGA-CV-6433-01A-11D-1683-08) from TCGA case TCGA-CV-6433, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 57.1 years (20,855 days).
Specimen TCGA-CV-6433-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aea46669-80a9-4321-ad98-5e76ee1c9e5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6433-11A (Solid Tissue Normal), aliquot TCGA-CV-6433-11A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02582b5c-9675-41c0-bc78-c5ae2045ce7a

The open-access MAF lists 53 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 34, Silent 12, Frame Shift Del 4, Splice Region 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHDC1 | c.4522C>G p.P1508A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99899552; called by muse, mutect2, varscan2
- ANKRD17 | c.5020A>C p.K1674Q | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.95); catalogued as COSV100429642; called by muse, mutect2, varscan2
- ARID1B | c.3229C>G p.L1077V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99270652; called by muse, mutect2, varscan2
- AXDND1 | c.2147T>G p.M716R | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100858540; called by muse, mutect2, varscan2
- CELSR3 | c.456T>A p.S152R | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99374313; called by muse, varscan2
- CELSR3 | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99374315; called by muse, varscan2
- CEP162 | c.3027G>T p.E1009D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV100003115; called by muse, mutect2, varscan2
- CFAP47 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52893445; called by muse, mutect2, varscan2
- CILP2 | c.1312T>G p.C438G | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99364975; called by muse, varscan2
- CSMD3 | c.1561G>A p.A521T (on ENST00000297405 / NM_001363185.1; = p.A417T on NM_052900.3) | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs140758499; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1191C>A p.D397E (on ENST00000361735 / NM_015935.5; = p.D311E on NM_014955.3) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100675962; called by muse, mutect2
- ELL | c.1774A>T p.K592* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99443521; called by muse, mutect2, varscan2
- EXOC3L2 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771973379, COSV99374587; called by muse, mutect2, varscan2
- GCDH | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as COSV55821838, COSV99712898; called by muse, mutect2, varscan2
- GPC3 | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.579); catalogued as COSV100893320; called by muse, mutect2, varscan2
- IGFN1 | c.2223G>A p.E741= (on ENST00000295591 / NM_001367841.1; = p.E3198= on NM_001164586.2) | Splice Region (SNP) | VAF 29/72 reads (40%) | catalogued as rs753856785, COSV55170006, COSV99812975; called by muse, mutect2, varscan2
- IP6K3 | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs753338065, COSV99540001; called by muse, mutect2, varscan2
- KIF3B | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV104424214, COSV65228907; called by muse, mutect2
- MAGEC1 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs746586268, COSV99596092; called by muse, mutect2, varscan2
- MUC17 | c.2951C>A p.P984Q | Missense Mutation (SNP) | VAF 96/262 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV100074331; called by muse, mutect2, varscan2
- NMUR2 | c.258C>A p.S86R | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54918810, COSV99677074; called by muse, mutect2, varscan2
- OR4C11 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs757013595, COSV56352176; called by muse, mutect2, varscan2
- PCDHGB6 | c.1133G>C p.G378A | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV99542629; called by muse, mutect2, varscan2
- PDGFRL | c.384G>T p.L128F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99286557; called by muse, mutect2, varscan2
- PRKG1 | c.620T>A p.I207N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100908950; called by muse, mutect2, varscan2
- RPS6KB2 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199664699, COSV100396663; called by muse, mutect2, varscan2
- RYR1 | c.5548G>A p.V1850M | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV100616402, COSV100617089; called by muse, mutect2, varscan2
- SACM1L | c.1170G>A p.M390I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101203782; called by muse, mutect2, varscan2
- SMARCA5 | c.2588A>G p.D863G | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99304011; called by muse, mutect2, varscan2
- SYBU | c.1715G>A p.R572H (on ENST00000276646 / NM_001099754.2; = p.R571H on NM_017786.6) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs200147690, COSV99406209; called by muse, varscan2
- TAF1 | c.3004C>T p.R1002C (on ENST00000373790 / NM_138923.4; = p.R1023C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52114997, COSV52118430; called by muse, mutect2, varscan2
- TEC | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV101202661; called by muse, mutect2
- TMEFF2 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs751243020, COSV99772008; called by muse, mutect2, varscan2
- ZNF292 | c.4846A>G p.R1616G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV100370770; called by muse, mutect2, varscan2
- ZNF835 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as COSV73379615; called by muse, mutect2, varscan2
- CILP2 | c.1299_1308del p.S434Afs*21 | Frame Shift Del (DEL) | VAF 30/79 reads (38%) | called by pindel, varscan2
- KCNH6 | c.216_224del p.N73_P75del | In Frame Del (DEL) | VAF 25/98 reads (26%) | called by mutect2, pindel, varscan2
- RNASE10 | c.311_327del p.Q104Pfs*2 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel
- TDRD7 | c.1296del p.E433Sfs*5 | Frame Shift Del (DEL) | VAF 23/111 reads (21%) | called by mutect2, pindel, varscan2
- TRAV14DV4 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); called by muse, mutect2
- UNC79 | c.2660_2661del p.V887Gfs*9 (on ENST00000393151 / NM_001346218.2; = p.V710Gfs*9 on NM_020818.5) | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- ACTN2 | c.2475C>T p.T825= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs758805815, COSV63978535; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH11 | c.1854C>T p.G618= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs372527203; called by muse, mutect2, varscan2
- CES2 | c.687G>A p.A229= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as rs150055059; called by muse, mutect2, varscan2
- GFRA1 | c.1363C>T p.L455= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100815889; called by muse, mutect2, varscan2
- GNRHR | c.738C>T p.P246= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV99892274; called by muse, mutect2, varscan2
- NAXE | c.639C>T p.P213= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100576972, COSV58041331; called by muse, mutect2
- PPP1R42 | c.15C>A p.T5= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100221398, COSV61209440; called by muse, mutect2, varscan2
- SCG3 | c.570A>G p.E190= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99591084; called by muse, mutect2, varscan2
- STRC | c.3729A>G p.E1243= | Silent (SNP) | VAF 55/250 reads (22%) | catalogued as COSV101372228; called by muse, mutect2
- TRIM2 | c.1965C>T p.F655= (on ENST00000437508; = p.F682= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100108093; called by muse, mutect2, varscan2
- UAP1L1 | c.1131C>T p.N377= | Silent (SNP) | VAF 55/122 reads (45%) | catalogued as rs368003866; called by muse, mutect2, varscan2
- UTRN | c.8550A>G p.Q2850= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs1470960776, COSV62312027; called by muse, mutect2, varscan2
